Gene-level copy-number profile of tumor specimen TCGA-KU-A66T-01A from TCGA case TCGA-KU-A66T, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.1 years (19,405 days).
Specimen TCGA-KU-A66T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0e34ade5-dd8c-4bfd-be7a-3bbd56c0f95c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KU-A66T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f6c60d7-3959-425d-aefc-8c8bb3fe986b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 952; copy number 2: 17,891; copy number 3: 21,421; copy number 4: 13,891; copy number 5: 2,081; copy number 6: 1,755; copy number 7: 929; copy number 8: 200; copy number 9: 136; copy number 10: 63; copy number 11: 46; copy number 12: 32; copy number 13: 124; copy number 15: 18; copy number 18: 142; copy number 20: 1; copy number 21: 25; copy number 22: 59; copy number 23: 27; copy number 27: 12; copy number 33: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KU-A66T-01A-11D-A30D-01): tumor purity 0.86, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–21,995,301, 1 gene: CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,807 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:231,241,207–239,915,452, 158 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr2:176,077,472–176,339,077, 21 genes, copy number 9: EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67.
- chr2:182,716,041–185,833,290, 31 genes, copy number 9–23: DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1, CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2.
- chr2:186,486,253–188,384,313, 15 genes, copy number 7–10 (within-gene range 6–10): ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2.
- chr5:64,404,512–68,198,407, 58 genes, copy number 8: AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB, NLN, AC008958.1, AC010359.2, ERBIN, AC010359.1, AC010359.3, AC025442.2, SREK1, AC025442.1, LINC02065, AC092353.1, AC092353.2, LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1, CD180, AC010420.1, AC008459.1, AC112206.2, AC079467.1, AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3, AC106798.1, AC024581.1, AC024581.2, AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219.
- chr7:54,542,325–57,837,046, 153 genes, copy number 8–21 (broad region; genes not listed).
- chr8:38,269,704–38,382,272, 1 gene, copy number 23 (within-gene range 6–23): NSD3.
- chr8:38,335,981–38,853,028, 14 genes, copy number 8–23 (within-gene range 6–23): AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1.
- chr8:42,896,197–43,131,180, 8 genes, copy number 11–20: MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1.
- chr8:53,162,339–53,162,987, 1 gene, copy number 18: AC009646.1.
- chr8:53,388,701–53,959,303, 13 genes, copy number 22 (within-gene range 2–22): AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P.
- chr11:69,294,151–69,367,726, 1 gene, copy number 22 (within-gene range 6–22): MYEOV.
- chr11:69,371,463–74,311,640, 171 genes, copy number 13–22 (broad region; genes not listed).
- chr11:131,370,478–132,336,822, 1 gene, copy number 8 (within-gene range 2–11): NTM.
- chr11:131,877,680–133,532,519, 9 genes, copy number 8–11 (within-gene range 2–11): AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1.
- chr12:66,767–34,249,958, 850 genes, copy number 7 (broad region; genes not listed).
- chr12:59,366,218–59,411,171, 1 gene, copy number 33 (within-gene range 6–33): AC108721.1.
- chr12:59,450,673–73,679,296, 248 genes, copy number 10–27 (broad region; genes not listed).
- chr12:84,147,304–84,449,878, 4 genes, copy number 11: AC090679.3, AC090679.2, AC090679.1, AC087888.1.
- chr19:5,158,495–5,778,734, 14 genes, copy number 9 (within-gene range 3–9): PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4, TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD.
- chr20:9,986,088–11,878,429, 35 genes, copy number 7–10 (within-gene range 4–10): PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1.

Autosomal genes at a single copy (total copy number 1): 428. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
